Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8110, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8110-01A (Primary Tumor).

Pathology Report for Subject [REDACTED]

Diagnosis: Anaplastic Astrocytoma (grade III)

Microscopic Description: Sections reveal a moderate hypercellular proliferation of moderately atypical fibrillary astrocytes which are diffusely invading the gray and matter matter. Scattered mitoses are noted. Necrosis or microvascular proliferation is not identified. A focus of acute and remote hemorrhage with degenerating surrounding parenchyma cannot be definitively interpreted as spontaneous necrosis.

Source: NCI Genomic Data Commons file f90f3fb3-5ab9-4be5-8c2f-4824791ed106 (TCGA-HT-8110.C423008B-608E-4260-B36C-21135A7FCD82.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).